Somatic mutation profile of tumor specimen MMRF_2253_1_BM_CD138pos (aliquot MMRF_2253_1_BM_CD138pos_T1_KHS5U_L09496) from MMRF case MMRF_2253, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.4 years (22,422 days).
Specimen MMRF_2253_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49a022f5-f4f0-4b69-b63d-2faacb8f3312.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2253_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2253_1_PB_Whole_C2_KHS5U_L09495; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d85e3e8-c4bb-4d3e-b8bb-ae4ff8e10024

The open-access MAF lists 106 somatic variants for this specimen: 36 protein-altering or splice-affecting, 11 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 29, Intron 17, Silent 11, 5'UTR 5, 3'Flank 4, 5'Flank 3, Splice Site 1, Splice Region 1, RNA 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CD2BP2 | c.162T>G p.D54E | Missense Mutation (SNP) | VAF 91/198 reads (46%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as rs183836873, COSV59769840; called by muse, mutect2, varscan2
- CELSR2 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 111/252 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs573558774; called by muse, mutect2, varscan2
- CMSS1 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.154); catalogued as rs768468210; called by muse, mutect2, varscan2
- HLCS | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 104/223 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs143463463, COSV100358467; called by muse, mutect2, varscan2
- IGHV2-70 | c.209C>G p.A70G | Missense Mutation (SNP) | VAF 72/73 reads (99%) | SIFT tolerated (1); PolyPhen benign (0.2); catalogued as rs534090956; called by muse, varscan2
- IGHV2-70 | c.158T>A p.M53K | Missense Mutation (SNP) | VAF 68/70 reads (97%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs1555607329; called by muse, varscan2
- IGHV3-23 | c.7T>C p.F3L | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as rs549572360; called by muse, varscan2
- ITIH5 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 79/145 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0.043); catalogued as rs887329530, COSV53670082; called by muse, mutect2, varscan2
- KCNJ2 | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs753215455, COSV54663887; called by muse, mutect2, varscan2
- KIF25 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs779727454, COSV63027318; called by muse, mutect2, varscan2
- LAMP5 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.655); catalogued as rs1467903187, COSV55717486; called by mutect2, varscan2
- LEMD3 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1565775067, COSV57650468; called by muse, mutect2, varscan2
- MFF | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.945); catalogued as rs535111295; called by mutect2, varscan2
- PCCB | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs760499581; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TDRD6 | c.3194T>C p.V1065A | Missense Mutation (SNP) | VAF 90/177 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276903726; called by muse, mutect2, varscan2
- TSHZ3 | c.2933G>T p.C978F | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53679410; called by muse, mutect2, varscan2
- CDCA2 | c.1535A>G p.Q512R | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- CHRNB1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DIS3 | c.1046T>G p.I349R | Missense Mutation (SNP) | VAF 82/83 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FYCO1 | c.1003A>G p.T335A | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRID2 | c.2719A>G p.I907V | Missense Mutation (SNP) | VAF 164/351 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGLL5 | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM2A | c.3407C>G p.A1136G | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- LRRTM4 | c.413T>G p.L138R | Missense Mutation (SNP) | VAF 106/208 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NACC2 | c.1435del p.L479Sfs*31 | Frame Shift Del (DEL) | VAF 18/150 reads (12%) | called by mutect2, pindel, varscan2
- OR56A4 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PARL | c.511+7G>A | Splice Region (SNP) | VAF 29/113 reads (26%) | called by muse, mutect2, varscan2
- PIK3C2G | c.3493G>T p.G1165* (on ENST00000676171; = p.G1124* on NM_004570.5) | Nonsense Mutation (SNP) | VAF 55/126 reads (44%) | called by muse, mutect2, varscan2
- RPAP1 | c.3883G>A p.A1295T | Missense Mutation (SNP) | VAF 44/268 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC2A5 | c.1330G>C p.V444L | Missense Mutation (SNP) | VAF 79/158 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SWT1 | c.1620C>A p.N540K | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TAF5 | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.01); called by muse, mutect2
- WDR83 | c.727C>G p.L243V | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- XIRP2 | c.199-1G>C p.X67_splice (on ENST00000628543; = p.X242_splice on NM_152381.6) | Splice Site (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- ZEB2 | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CACNA1D | c.1188C>T p.F396= | Silent (SNP) | VAF 66/141 reads (47%) | catalogued as rs757944029, COSV55450352; called by muse, mutect2, varscan2
- COQ9 | c.783C>T p.D261= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as rs1248544273; called by muse, mutect2, varscan2
- CSMD3 | c.5979G>A p.L1993= (on ENST00000297405 / NM_001363185.1; = p.L1889= on NM_052900.3) | Silent (SNP) | VAF 30/202 reads (15%) | catalogued as COSV52226804, COSV52298928; called by muse, mutect2, varscan2
- DNPH1 | c.123G>A p.R41= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs1306981798; called by muse, mutect2, varscan2
- EIF2B1 | c.69A>C p.A23= | Silent (SNP) | VAF 155/317 reads (49%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.6G>A p.E2= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as rs192001086; called by muse, varscan2
- NACC2 | c.171C>T p.D57= | Silent (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- NLRP4 | c.759G>A p.E253= | Silent (SNP) | VAF 108/205 reads (53%) | called by muse, mutect2, varscan2
- NUAK2 | c.642C>G p.L214= | Silent (SNP) | VAF 39/169 reads (23%) | catalogued as COSV65681144; called by muse, mutect2, varscan2
- PRRC2B | c.6459G>A p.S2153= | Silent (SNP) | VAF 36/245 reads (15%) | catalogued as rs748614445, COSV57645613; called by muse, mutect2, varscan2
- TRANK1 | c.6909T>C p.F2303= | Silent (SNP) | VAF 7/135 reads (5%) | called by muse, mutect2
- AC079228.1 | n.432T>A | RNA (SNP) | VAF 67/156 reads (43%) | called by muse, mutect2, varscan2
- ADAMTS9 | c.1464-480G>A | Intron (SNP) | VAF 50/110 reads (45%) | called by muse, mutect2, varscan2
- ALG13 | c.383+3108T>C | Intron (SNP) | VAF 15/28 reads (54%) | called by mutect2, varscan2
- ANO3 | c.*2783T>A | 3'UTR (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- ANTXR1 | c.*510C>A | 3'UTR (SNP) | VAF 63/140 reads (45%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500953 G>A | 5'Flank (SNP) | VAF 60/146 reads (41%) | called by muse, mutect2, varscan2
- ARL14EP | c.-63-927T>G | Intron (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- ARL14EP | c.-63-926T>C | Intron (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- BRD1 | c.*142C>G | 3'UTR (SNP) | VAF 7/24 reads (29%) | catalogued as rs888815172; called by muse, mutect2, varscan2
- CARMIL3 | c.2707-96G>A | Intron (SNP) | VAF 21/35 reads (60%) | called by muse, mutect2, varscan2
- CBX1 | c.*968G>A | 3'UTR (SNP) | VAF 227/484 reads (47%) | called by muse, mutect2, varscan2
- CCDC77 | c.*530G>T | 3'UTR (SNP) | VAF 44/106 reads (42%) | called by muse, mutect2, varscan2
- CCND1 | c.*1973G>T | 3'UTR (SNP) | VAF 43/232 reads (19%) | catalogued as rs1485315433; called by muse, mutect2, varscan2
- CLN8 | c.*5590C>G | 3'UTR (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+11642G>A | Intron (SNP) | VAF 33/244 reads (14%) | catalogued as rs151204827; called by muse, mutect2, varscan2
- CXCL9 | c.*503T>C | 3'UTR (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- DDX11 | c.-4-215C>A | Intron (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- ERGIC1 | c.375+2769A>G | Intron (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2, varscan2
- ETV1 | chr7:13893371 A>C | 3'Flank (SNP) | VAF 51/106 reads (48%) | called by muse, mutect2, varscan2
- FAM107B | chr10:14519072 C>G | 3'Flank (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- FCAR | c.649+101G>A | Intron (SNP) | VAF 9/30 reads (30%) | catalogued as rs1177393932; called by muse, mutect2, varscan2
- FGFBP3 | c.*1008A>C | 3'UTR (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- FRMD4B | c.*849T>C | 3'UTR (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- GULP1 | c.*1308C>T | 3'UTR (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- HPCAL4 | c.*489A>T | 3'UTR (SNP) | VAF 28/114 reads (25%) | called by muse, mutect2, varscan2
- HPS5 | c.1511-93T>C | Intron (SNP) | VAF 33/73 reads (45%) | called by muse, mutect2, varscan2
- HSD17B7 | c.447+96A>G | Intron (SNP) | VAF 16/454 reads (4%) | called by muse, mutect2
- LCN8 | c.295+188C>T | Intron (SNP) | VAF 159/525 reads (30%) | called by muse, mutect2, varscan2
- LRBA | c.4569+3130C>T | Intron (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- LRRC8A | c.*247G>A | 3'UTR (SNP) | VAF 10/119 reads (8%) | called by muse, mutect2
- MADD | c.*544G>A | 3'UTR (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- NAGK | c.668-14C>T | Intron (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2
- NSUN6 | c.-334G>A | 5'UTR (SNP) | VAF 38/77 reads (49%) | catalogued as rs1023098301; called by muse, mutect2, varscan2
- NUS1 | c.*1559A>T | 3'UTR (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- OPCML | c.*5037T>C | 3'UTR (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- PAXIP1 | c.1893+73A>C | Intron (SNP) | VAF 40/76 reads (53%) | called by muse, mutect2, varscan2
- PCSK5 | c.2626+5557A>G | Intron (SNP) | VAF 83/127 reads (65%) | called by muse, mutect2, varscan2
- PKN2 | c.*2195G>A | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- PMP22 | c.*50G>A | 3'UTR (SNP) | VAF 17/346 reads (5%) | called by muse, mutect2
- PNMA8A | c.*164A>T | 3'UTR (SNP) | VAF 77/157 reads (49%) | called by muse, mutect2, varscan2
- RAD1 | chr5:34905483 del TTA | 3'Flank (DEL) | VAF 54/112 reads (48%) | called by mutect2, pindel, varscan2
- RNF144B | c.*311C>G | 3'UTR (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- RPL32 | c.-40T>A | 5'UTR (SNP) | VAF 8/200 reads (4%) | called by muse, mutect2
- S1PR5 | c.*84G>T | 3'UTR (SNP) | VAF 9/20 reads (45%) | catalogued as rs1295225315; called by muse, mutect2
- SDCBP | c.-15-4313C>A | Intron (SNP) | VAF 70/144 reads (49%) | called by muse, mutect2, varscan2
- SEPTIN10 | chr2:109613975 G>A | 5'Flank (SNP) | VAF 8/29 reads (28%) | catalogued as rs1028775209; called by muse, mutect2
- SF3B6 | c.-74G>A | 5'UTR (SNP) | VAF 40/165 reads (24%) | catalogued as COSV51980102; called by muse, mutect2, varscan2
- SIGLEC10 | chr19:51417740 C>T | 5'Flank (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- SIX6 | c.*828A>G | 3'UTR (SNP) | VAF 37/72 reads (51%) | catalogued as rs1286858739; called by muse, mutect2, varscan2
- SLFN13 | c.*4342A>T | 3'UTR (SNP) | VAF 77/166 reads (46%) | called by muse, mutect2, varscan2
- SLITRK2 | c.-283dup | 5'UTR (INS) | VAF 49/69 reads (71%) | catalogued as rs1488507370; called by mutect2, pindel, varscan2
- STAM2 | c.*1419G>C | 3'UTR (SNP) | VAF 53/122 reads (43%) | called by muse, mutect2, varscan2
- UBE2D3 | chr4:102794673 ins AAACA | 3'Flank (INS) | VAF 8/43 reads (19%) | called by pindel, varscan2*
- UBE2H | c.*430G>T | 3'UTR (SNP) | VAF 35/74 reads (47%) | called by muse, mutect2, varscan2
- UNKL | c.*639A>G | 3'UTR (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- UPF1 | c.-7A>G | 5'UTR (SNP) | VAF 22/111 reads (20%) | catalogued as rs762027013; called by muse, mutect2, varscan2
- ZMAT2 | c.*830A>C | 3'UTR (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- ZNF275 | c.*579C>A | 3'UTR (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- ZNF703 | c.*609G>T | 3'UTR (SNP) | VAF 37/70 reads (53%) | called by muse, mutect2, varscan2
